Gene-level copy-number profile of tumor specimen HTMCP-02-03-01006-01A from CGCI case HTMCP-02-03-01006, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Combined small cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.5 years (20,636 days).
Specimen HTMCP-02-03-01006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b47cb44e-786d-4b76-a76c-c5d191c8e393.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01006-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/7b9141b0-3eaa-43ba-a8b6-74597fbc3263

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 18; copy number 2: 13,323; copy number 3: 9,185; copy number 4: 23,794; copy number 5: 6,761; copy number 6: 4,551; copy number 7: 323; copy number 8: 130; copy number 9: 5; copy number 10: 76; copy number 11: 663; copy number 12: 40; copy number 15: 4; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr19:54,216,278–54,230,213, 3 genes (within-gene range 0–2): LILRB3, AC245052.7, AC245052.3.
- chr22:22,689,831–22,739,187, 12 genes (within-gene range 0–3): AC244250.2, AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 789 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,745,249–145,708,148, 60 genes, copy number 10: AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1.
- chr1:148,482,548–149,747,818, 33 genes, copy number 10–12: PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr1:206,147,164–206,464,443, 6 genes, copy number 12: AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1.
- chr2:113,325,372–113,425,548, 1 gene, copy number 9 (within-gene range 4–9): AC016745.1.
- chr2:113,432,600–113,496,204, 2 genes, copy number 9: AC016745.2, CBWD2.
- chr5:58,198–45,895,970, 679 genes, copy number 9–15 (broad region; genes not listed).
- chr14:18,333,726–18,341,859, 1 gene, copy number 18: CR383658.1.
- chr17:46,372,855–46,757,464, 7 genes, copy number 11 (within-gene range 6–11): NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
